Somatic mutation profile of tumor specimen 4683de9c-49ca-4ddd-9d1a-be8121 (aliquot 4683de9c-49ca-4ddd-9d1a-be8121_D6) from CPTAC case 03BR004, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 88.6 years (32,363 days).
Specimen 4683de9c-49ca-4ddd-9d1a-be8121: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e12adaa0-b6f0-479c-9a80-815c5830ea7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 195a74d7-12c8-498d-9b63-c67177 (Blood Derived Normal), aliquot 195a74d7-12c8-498d-9b63-c67177_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8378c6a-b14b-4b74-9eb1-7fc6cf45d265

The open-access MAF lists 40 somatic variants for this specimen: 30 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 5, Frame Shift Del 3, Intron 2, Nonsense Mutation 2, 3'UTR 2, Frame Shift Ins 1, RNA 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APEH | c.361del p.L121Wfs*71 | Frame Shift Del (DEL) | VAF 37/310 reads (12%) | catalogued as COSV56521554, COSV99610326; called by mutect2, pindel, varscan2
- COL6A5 | c.6451G>A p.A2151T (on ENST00000312481; = p.A2147T on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs751453334; called by muse, mutect2, varscan2
- DHODH | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 88/304 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as rs746657681, COSV54663100; called by muse, mutect2, varscan2
- F9 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as CM940449, COSV54382464; called by muse, mutect2, varscan2
- INMT | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 54/420 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs767449565, COSV50000684; called by muse, mutect2, varscan2
- MAP3K1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781300314, COSV68122102, COSV68123119; called by muse, mutect2, varscan2
- NUMA1 | c.3544C>T p.Q1182* | Nonsense Mutation (SNP) | VAF 49/316 reads (16%) | catalogued as COSV100705754; called by muse, mutect2, varscan2
- PCDHA6 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 25/570 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV67056572; called by muse, mutect2
- PKHD1 | c.10660G>A p.E3554K | Missense Mutation (SNP) | VAF 29/594 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV64386909, COSV64391751; called by muse, mutect2
- PSG3 | c.711G>A p.P237= | Splice Region (SNP) | VAF 43/197 reads (22%) | catalogued as rs2353157, COSV59505528; called by muse, mutect2, varscan2
- SAMD14 | c.155G>C p.R52P | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as COSV53309365, COSV99557573; called by mutect2, varscan2
- SLC12A6 | c.2969G>A p.R990H (on ENST00000354181 / NM_001365088.1; = p.R939H on NM_005135.2) | Missense Mutation (SNP) | VAF 18/554 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs868273832, COSV51625658; called by muse, mutect2
- TLE4 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs775594827, COSV54630951; called by muse, mutect2, varscan2
- TP53 | c.997del p.R333Vfs*12 | Frame Shift Del (DEL) | VAF 68/220 reads (31%) | catalogued as CM137619, COSV52774724; called by mutect2, pindel, varscan2
- WASF1 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1037010853; called by muse, mutect2
- ZFHX3 | c.4203C>A p.Y1401* | Nonsense Mutation (SNP) | VAF 38/155 reads (25%) | catalogued as COSV51728391; called by mutect2, varscan2
- ZNF750 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV53959594; called by muse, mutect2
- ADGRA3 | c.732C>G p.F244L | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.728); called by muse, mutect2
- AP5M1 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- CHRM1 | c.612G>T p.M204I | Missense Mutation (SNP) | VAF 56/357 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- FANCM | c.1876C>G p.P626A | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GABRG3 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- GUCA1C | c.172G>C p.D58H | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- KIFC3 | c.61C>T p.H21Y | Missense Mutation (SNP) | VAF 30/115 reads (26%) | PolyPhen benign (0.3); called by muse, mutect2, varscan2
- MAP3K1 | c.3959dup p.N1320Kfs*5 | Frame Shift Ins (INS) | VAF 22/135 reads (16%) | called by mutect2, pindel, varscan2
- PBX2 | c.1147G>C p.G383R | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.049); called by muse, mutect2
- PTEN | c.724_726delinsT p.E242Ffs*10 | Frame Shift Del (DEL) | VAF 54/227 reads (24%) | called by pindel, varscan2*
- RHOH | c.117G>C p.E39D | Missense Mutation (SNP) | VAF 64/329 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RIMBP3 | c.1894G>C p.V632L | Missense Mutation (SNP) | VAF 31/396 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); called by muse, mutect2
- SIGLEC1 | c.5129G>T p.*1710Lext*25 | Nonstop Mutation (SNP) | VAF 54/264 reads (20%) | called by muse, mutect2, varscan2
- BMI1 | c.46C>T p.L16= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as rs553308542; called by muse, mutect2, varscan2
- PRKG2 | c.1683A>T p.T561= | Silent (SNP) | VAF 39/118 reads (33%) | called by muse, mutect2, varscan2
- RYR1 | c.3960C>T p.D1320= | Silent (SNP) | VAF 38/662 reads (6%) | catalogued as rs768095292, COSV62109998; ClinVar: likely benign; called by muse, mutect2
- SLC38A3 | c.1050G>A p.S350= | Silent (SNP) | VAF 42/159 reads (26%) | catalogued as rs143416058, COSV101309876; called by muse, mutect2, varscan2
- ZNF595 | c.21G>A p.R7= | Silent (SNP) | VAF 14/252 reads (6%) | catalogued as COSV100227888, COSV59548836; called by muse, mutect2
- AL035696.1 | n.227G>A | RNA (SNP) | VAF 41/209 reads (20%) | called by muse, mutect2, varscan2
- C12orf43 | c.188+19T>A | Intron (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- KIAA1841 | c.1865+33C>T | Intron (SNP) | VAF 14/366 reads (4%) | called by muse, mutect2
- MYO1H | c.*29G>A | 3'UTR (SNP) | VAF 42/193 reads (22%) | catalogued as rs189950317; called by muse, mutect2, varscan2
- POU2F2 | c.*31C>T | 3'UTR (SNP) | VAF 20/157 reads (13%) | catalogued as rs1373109156; called by muse, mutect2, varscan2
